Somatic mutation profile of tumor specimen C3N-03222-01 (aliquot CPT0179140006) from CPTAC case C3N-03222, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 72.9 years (26,630 days).
Specimen C3N-03222-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdf33b83-1208-4680-8e36-08f5fd24951c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03222-71 (Blood Derived Normal), aliquot CPT0179260002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c0af384-61e2-4caf-bc5b-3da0232cd9de

The open-access MAF lists 538 somatic variants for this specimen: 366 protein-altering or splice-affecting, 112 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 302, Silent 112, Nonsense Mutation 27, Intron 23, 5'UTR 13, Frame Shift Del 12, Splice Site 9, RNA 8, 3'UTR 7, Splice Region 7, 3'Flank 6, Frame Shift Ins 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>A p.S310Y | Missense Mutation (SNP) | VAF 40/420 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2
- PKD1 | c.7927C>T p.R2643C | Missense Mutation (SNP) | VAF 114/1061 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1452322332, CD123955, CM074416; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC139530.2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.505); catalogued as rs746999164; called by muse, mutect2, varscan2
- ADGRG3 | c.768G>T p.L256= | Splice Region (SNP) | VAF 77/269 reads (29%) | catalogued as rs779745262, COSV59650613; called by muse, mutect2, varscan2
- ADGRL3 | c.455A>G p.Y152C (on ENST00000506720 / NM_001322402.2; = p.Y84C on NM_015236.6) | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV72268425; called by muse, mutect2, varscan2
- ADGRL4 | c.590C>A p.T197N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV100876231; called by muse, mutect2
- ADRA1A | c.1352C>A p.T451N | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.326); catalogued as COSV52361925; called by muse, mutect2, varscan2
- AGAP3 | c.1936G>A p.A646T (on ENST00000622464; = p.A682T on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs1187609862; called by muse, mutect2, varscan2
- AMBRA1 | c.1705C>G p.R569G (on ENST00000458649 / NM_001367468.1; = p.R479G on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/474 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV54053670; called by muse, mutect2, varscan2
- AMPH | c.2051del p.G684Afs*11 | Frame Shift Del (DEL) | VAF 30/145 reads (21%) | catalogued as COSV100342439; called by mutect2, pindel, varscan2
- ANKS1B | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 67/239 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61357670, COSV61377939; called by muse, mutect2, varscan2
- ARHGAP20 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52816638; called by muse, mutect2, varscan2
- ARHGAP32 | c.2189C>A p.S730Y (on ENST00000310343 / NM_001378025.1; = p.S381Y on NM_014715.4) | Missense Mutation (SNP) | VAF 110/182 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs941872326; called by muse, varscan2
- ATP6V0A4 | c.639G>T p.T213= | Splice Region (SNP) | VAF 296/661 reads (45%) | catalogued as rs754335968, COSV100023424; called by muse, mutect2, varscan2
- ATRNL1 | c.2019T>A p.C673* | Nonsense Mutation (SNP) | VAF 27/187 reads (14%) | catalogued as COSV100745419; called by muse, mutect2, varscan2
- BMI1 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100936402; called by muse, mutect2, varscan2
- BRINP3 | c.2134A>G p.K712E | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV66521881; called by muse, mutect2, varscan2
- BVES | c.125A>G p.H42R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs201357569; called by muse, mutect2, varscan2
- C1QTNF9 | c.684T>A p.Y228* | Nonsense Mutation (SNP) | VAF 52/137 reads (38%) | catalogued as rs780122653; called by muse, mutect2, varscan2
- C1orf74 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 104/331 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371501062; called by muse, mutect2, varscan2
- CDH9 | c.1354C>A p.P452T | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.216); catalogued as rs1483541355; called by muse, mutect2, varscan2
- CFAP46 | c.5533G>C p.G1845R | Missense Mutation (SNP) | VAF 52/372 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.025); catalogued as COSV99583730; called by muse, mutect2, varscan2
- CROCC2 | c.1823T>C p.L608P | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as rs962358457; called by muse, mutect2, varscan2
- CTNNA2 | c.569C>A p.A190E | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100785650; called by muse, mutect2, varscan2
- CUX1 | c.2367G>T p.Q789H | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.188); catalogued as COSV99471488; called by muse, mutect2, varscan2
- CYRIB | c.611C>G p.A204G | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV67830007; called by muse, mutect2
- DDX4 | c.512C>A p.P171Q | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV61753526; called by muse, mutect2, varscan2
- DECR2 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1167137366; called by muse, mutect2, varscan2
- DLL3 | c.1513G>A p.V505M | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs111556824, COSV99218960; called by muse, mutect2, varscan2
- DPF3 | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 91/262 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); catalogued as COSV63501617; called by muse, mutect2, varscan2
- DST | c.13517C>T p.A4506V (on ENST00000361203 / NM_001374722.1; = p.A2094V on NM_015548.5) | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.065); catalogued as rs181741923; called by muse, mutect2
- DYNC2H1 | c.10222A>G p.I3408V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs1325402584; called by muse, mutect2, varscan2
- EGFR | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 48/299 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs375919121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EHMT1 | c.1982C>T p.S661L | Missense Mutation (SNP) | VAF 98/236 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs576113368, COSV58379033; called by muse, mutect2, varscan2
- EPB41L3 | c.1883G>C p.R628P | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.885); catalogued as COSV59443056, COSV59462472; called by muse, mutect2, varscan2
- FAM120C | c.2509G>A p.A837T | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60259553; called by muse, mutect2
- FAM98A | c.656G>A p.R219K | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV53210754; called by muse, mutect2
- FAP | c.1815-6C>A | Splice Region (SNP) | VAF 13/30 reads (43%) | catalogued as rs746482757; called by muse, mutect2
- FAT4 | c.13464del p.H4489Mfs*5 | Frame Shift Del (DEL) | VAF 100/312 reads (32%) | catalogued as COSV58671097; called by mutect2, pindel, varscan2
- FCRL3 | c.1562C>A p.S521* | Nonsense Mutation (SNP) | VAF 55/519 reads (11%) | catalogued as COSV63842428; called by muse, mutect2, varscan2
- FEZF2 | c.915C>G p.F305L | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV51864441, COSV99032466; called by muse, mutect2, varscan2
- FGA | c.2437C>T p.Q813* | Nonsense Mutation (SNP) | VAF 12/117 reads (10%) | catalogued as COSV100120546; called by muse, mutect2, varscan2
- FGB | c.1330G>T p.G444C | Missense Mutation (SNP) | VAF 76/494 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM033614, COSV57418067; called by muse, mutect2, varscan2
- FLG | c.5729C>A p.T1910K | Missense Mutation (SNP) | VAF 333/732 reads (45%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.755); catalogued as rs550114260; called by muse, mutect2, varscan2
- FOXF1 | c.286G>C p.V96L | Missense Mutation (SNP) | VAF 265/871 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM135692; called by muse, mutect2, varscan2
- GAK | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs566715038; called by muse, mutect2, varscan2
- GNG2 | c.185G>T p.R62M | Missense Mutation (SNP) | VAF 121/334 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58917655; called by muse, mutect2, varscan2
- GRIA1 | c.961G>T p.G321W | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV53606676; called by muse, mutect2, varscan2
- GUCY1A2 | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV56484063, COSV99977339; called by muse, mutect2, varscan2
- HECW1 | c.3735G>T p.Q1245H | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67841647; called by muse, mutect2, varscan2
- HRNR | c.2906G>C p.R969T | Missense Mutation (SNP) | VAF 227/853 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs753942220; called by muse, mutect2, varscan2
- ITGAX | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1338575506; called by muse, mutect2, varscan2
- KEAP1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV50260447, COSV50260545; called by muse, mutect2, varscan2
- KIAA1109 | c.2881A>G p.I961V | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1449765019; called by muse, mutect2, varscan2
- KIF19 | c.106A>G p.K36E | Missense Mutation (SNP) | VAF 106/319 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1020566516, COSV63430552; called by muse, mutect2, varscan2
- KMT2D | c.9431C>T p.A3144V | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs558965718, COSV56461655; called by muse, mutect2, varscan2
- KRTAP6-3 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 38/475 reads (8%) | PolyPhen probably damaging (0.982); catalogued as COSV101196498, COSV66963111; called by muse, mutect2
- LAMA2 | c.2549G>C p.G850A | Missense Mutation (SNP) | VAF 108/308 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs34487290; called by muse, mutect2, varscan2
- LILRB5 | c.1262C>G p.S421C | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as COSV60261440; called by muse, mutect2, varscan2
- LINGO2 | c.213C>G p.S71R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.244); catalogued as rs750851501, COSV58058696, COSV58059479; called by muse, mutect2
- LRP1B | c.13660-1G>T p.X4554_splice | Splice Site (SNP) | VAF 4/21 reads (19%) | catalogued as COSV67226383; called by muse, mutect2
- LRRC37B | c.1784C>A p.P595H | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146503923; called by muse, mutect2, varscan2
- LRRC53 | c.835G>C p.V279L | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV53952998; called by muse, mutect2, varscan2
- MAP3K5 | c.1756A>G p.I586V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763259352; called by muse, mutect2, varscan2
- MED12 | c.2456G>A p.R819Q | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV100376252; called by muse, mutect2, varscan2
- MYH1 | c.3454G>A p.E1152K | Missense Mutation (SNP) | VAF 147/423 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs759467878, COSV56848963; called by muse, mutect2, varscan2
- MYOM2 | c.497G>A p.W166* | Nonsense Mutation (SNP) | VAF 33/312 reads (11%) | catalogued as rs1430173927; called by muse, mutect2, varscan2
- NACAD | c.1816C>G p.L606V | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV71989594; called by muse, mutect2, varscan2
- NAV3 | c.3998C>A p.P1333Q | Missense Mutation (SNP) | VAF 80/240 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1182786175; called by muse, mutect2, varscan2
- NFATC1 | c.736G>C p.V246L | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.275); catalogued as rs773206226, COSV53702662; called by muse, mutect2, varscan2
- NLRP3 | c.1266G>T p.Q422H | Missense Mutation (SNP) | VAF 71/272 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100276571; called by muse, mutect2, varscan2
- NPAS1 | c.1369C>G p.Q457E | Missense Mutation (SNP) | VAF 203/699 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV53409599; called by muse, mutect2, varscan2
- NUTM1 | c.463C>A p.P155T | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.021); catalogued as COSV100412509; called by muse, mutect2, varscan2
- OR2G6 | c.425C>A p.A142E | Missense Mutation (SNP) | VAF 80/313 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.209); catalogued as COSV58574053; called by muse, mutect2, varscan2
- OR2T1 | c.283G>C p.G95R | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100822314; called by muse, mutect2, varscan2
- OR2W3 | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV64456469; called by muse, mutect2, varscan2
- OR4A15 | c.15C>A p.N5K | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.056); catalogued as rs534202398, COSV59035800; called by muse, mutect2, varscan2
- OR51I2 | c.143C>A p.A48D | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV100413479; called by muse, mutect2, varscan2
- OR8J3 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.732); catalogued as COSV56882607; called by muse, mutect2, varscan2
- PAGR1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.116); catalogued as COSV100232741; called by muse, mutect2
- PDZD7 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 49/330 reads (15%) | catalogued as rs771163176, COSV64647807, COSV64648003, COSV99058718; called by muse, mutect2, varscan2
- PGK2 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 23/241 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59162850; called by muse, mutect2
- PKP1 | c.1945G>A p.G649S | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as rs373741646; called by muse, mutect2, varscan2
- PLEC | c.3106C>T p.L1036F (on ENST00000322810 / NM_201380.4; = p.L926F on NM_000445.5) | Missense Mutation (SNP) | VAF 176/694 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as rs782687453; called by muse, mutect2, varscan2
- POLL | c.1114C>T p.Q372* | Nonsense Mutation (SNP) | VAF 66/378 reads (17%) | catalogued as COSV100150380; called by muse, mutect2, varscan2
- POM121L12 | c.208C>G p.R70G | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV68693461, COSV68693644; called by muse, mutect2, varscan2
- PRDM9 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 40/438 reads (9%) | catalogued as COSV57005428; called by muse, mutect2
- RPGRIP1 | c.2140C>G p.L714V | Missense Mutation (SNP) | VAF 69/247 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs755065072, COSV52855152; called by muse, mutect2, varscan2
- RTL4 | c.494C>A p.T165N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.046); catalogued as rs772215118; called by muse, varscan2
- SALL1 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs780538500; called by muse, mutect2, varscan2
- SIRPB1 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 121/601 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV99498299; called by muse, mutect2, varscan2
- SLC2A10 | c.1405C>G p.L469V | Missense Mutation (SNP) | VAF 50/676 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.332); catalogued as COSV63715891; called by muse, mutect2
- SLX4 | c.3950C>T p.P1317L | Missense Mutation (SNP) | VAF 113/408 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.523); catalogued as rs375172024; called by muse, mutect2, varscan2
- SORCS3 | c.1305C>T p.D435= | Splice Region (SNP) | VAF 13/64 reads (20%) | catalogued as rs368369848; called by muse, mutect2, varscan2
- SPRING1 | c.19A>G p.M7V | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs557048187; called by muse, mutect2, varscan2
- SRRM3 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as rs963545993; called by muse, mutect2, varscan2
- SUMF1 | c.603-2A>T p.X201_splice | Splice Site (SNP) | VAF 36/266 reads (14%) | catalogued as CD031567, CS124847; called by muse, mutect2, varscan2
- TFAP2D | c.514G>C p.A172P | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV50415566; called by muse, mutect2
- TNXB | c.6646C>A p.P2216T (on ENST00000647633; = p.P1969T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.814); catalogued as COSV64474808; called by muse, mutect2, varscan2
- TP53INP1 | c.571C>G p.P191A | Missense Mutation (SNP) | VAF 99/451 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.066); catalogued as COSV61332232; called by muse, mutect2, varscan2
- TRAM1L1 | c.916A>G p.T306A | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.071); catalogued as rs1303012910; called by muse, mutect2, varscan2
- TRPC7 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as rs748800350; called by muse, mutect2, varscan2
- TRRAP | c.2642G>A p.R881H | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs782386735, COSV62854858; called by muse, mutect2, varscan2
- UGT3A2 | c.1527G>T p.M509I | Missense Mutation (SNP) | VAF 73/234 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV56933753; called by muse, mutect2, varscan2
- UTF1 | c.349C>A p.R117S | Missense Mutation (SNP) | VAF 56/299 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV58678096; called by muse, mutect2, varscan2
- WDFY3 | c.9256A>G p.I3086V | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0.011); catalogued as rs764910573; called by muse, mutect2, varscan2
- WDFY4 | c.6097C>G p.L2033V | Missense Mutation (SNP) | VAF 62/395 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.185); catalogued as COSV55422383; called by muse, mutect2, varscan2
- XYLT2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 15/127 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV50019407; called by muse, mutect2, varscan2
- ZFP42 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV58817208, COSV58818962; called by muse, mutect2, varscan2
- ZNF235 | c.1084C>G p.L362V | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV52158297; called by muse, mutect2
- ZNF28 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 45/311 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs752696277; called by muse, mutect2, varscan2
- ZNF28 | c.1683T>G p.S561R | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.192); catalogued as rs1260323006; called by muse, mutect2, varscan2
- ZNF423 | c.1390C>G p.L464V (on ENST00000563137 / NM_001379286.1; = p.L456V on NM_015069.4) | Missense Mutation (SNP) | VAF 112/394 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV52191008; called by muse, mutect2, varscan2
- ZNF479 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 74/436 reads (17%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.069); catalogued as rs1300207130, COSV58638477; called by muse, mutect2, varscan2
- ZNF512 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.14); catalogued as COSV62675621; called by muse, mutect2, varscan2
- ABCA5 | c.4369_4373del p.D1457Tfs*22 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | called by mutect2, pindel, varscan2
- ACOD1 | c.307del p.H103Tfs*13 | Frame Shift Del (DEL) | VAF 94/277 reads (34%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.3026C>T p.T1009I | Missense Mutation (SNP) | VAF 79/404 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRL2 | c.1691G>T p.R564I | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ADIPOR1 | c.1000-1G>T p.X334_splice | Splice Site (SNP) | VAF 21/89 reads (24%) | called by muse, mutect2, varscan2
- ALDH9A1 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 93/213 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALMS1 | c.6009A>G p.I2003M | Missense Mutation (SNP) | VAF 34/282 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ANKRD24 | c.1967G>T p.G656V | Missense Mutation (SNP) | VAF 117/350 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ANKRD36C | c.4101del p.E1368Kfs*9 | Frame Shift Del (DEL) | VAF 20/126 reads (16%) | called by mutect2, varscan2
- AOC1 | c.1759T>A p.W587R | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- APEX1 | c.58+4A>T | Splice Region (SNP) | VAF 187/626 reads (30%) | called by muse, mutect2, varscan2
- ARHGEF12 | c.503A>T p.H168L | Missense Mutation (SNP) | VAF 92/245 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ARHGEF5 | c.4069A>T p.N1357Y | Missense Mutation (SNP) | VAF 31/291 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ASCC1 | c.965G>A p.R322K (on ENST00000342444 / NM_001369085.1; = p.R294K on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- AZI2 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2
- BAZ1A | c.956C>G p.S319* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- BRINP3 | c.871T>A p.C291S | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2
- BTLA | c.259A>G p.T87A | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- BUB1 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 74/245 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C1QTNF7 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1QTNF9B | c.684T>A p.Y228* | Nonsense Mutation (SNP) | VAF 16/162 reads (10%) | called by muse, mutect2
- CASP6 | c.251A>T p.E84V | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2
- CAVIN3 | c.352G>C p.A118P | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.731); called by muse, mutect2
- CCDC168 | c.19241del p.N6414Ifs*7 | Frame Shift Del (DEL) | VAF 16/83 reads (19%) | called by mutect2, pindel, varscan2
- CCDC175 | c.681G>T p.R227S | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- CCDC88B | c.2201T>G p.V734G | Missense Mutation (SNP) | VAF 58/363 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CDK15 | c.1055A>G p.N352S (on ENST00000652192 / NM_001366386.2; = p.N301S on NM_139158.2) | Missense Mutation (SNP) | VAF 52/349 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDKN1C | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CELSR3 | c.3119T>A p.V1040E | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CFAP46 | c.5306G>A p.R1769K | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP46 | c.4764G>C p.E1588D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- CFAP69 | c.2771A>G p.Q924R | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CFHR5 | c.430+1G>A p.X144_splice | Splice Site (SNP) | VAF 25/225 reads (11%) | called by muse, mutect2, varscan2
- CHST7 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 57/158 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- CIZ1 | c.347C>A p.T116K | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CNBD1 | c.529del p.L177Cfs*28 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | called by mutect2, pindel, varscan2
- CNMD | c.18C>A p.D6E | Missense Mutation (SNP) | VAF 10/255 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- COL10A1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- COL23A1 | c.1300T>G p.L434V | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- CSMD1 | c.8033C>A p.A2678D (on ENST00000520002; = p.A2677D on NM_033225.6) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- CSNK2A1 | c.444C>A p.H148Q | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSNK2A3 | c.617A>G p.Y206C | Missense Mutation (SNP) | VAF 62/442 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTCFL | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 87/290 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CYP1A1 | c.1081G>C p.D361H | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CYRIB | c.613A>G p.T205A | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.309); called by muse, mutect2
- DCAF4 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 7/204 reads (3%) | called by muse, mutect2
- DCBLD2 | c.703C>A p.P235T | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- DDX43 | c.164C>G p.S55C | Missense Mutation (SNP) | VAF 96/368 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- DISP2 | c.1858C>T p.L620F | Missense Mutation (SNP) | VAF 53/243 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- DNAH14 | c.6395G>A p.R2132K (on ENST00000445597; = p.R2785K on NM_001367479.1) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.047); called by muse, varscan2
- DNAH7 | c.9897A>T p.K3299N | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOP1B | c.6707C>G p.S2236C | Missense Mutation (SNP) | VAF 87/272 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- DPP6 | c.19A>T p.R7W | Missense Mutation (SNP) | VAF 190/485 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- DSCAM | c.5558A>T p.E1853V | Missense Mutation (SNP) | VAF 40/329 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- DYNC2H1 | c.11980A>G p.S3994G | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- E2F4 | c.35dup p.T14Hfs*29 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- EEA1 | c.4234_4235del p.*1412Mfs*12 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | called by mutect2, pindel*, varscan2*
- EPN2 | c.1012A>C p.M338L | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- EVA1B | c.170C>A p.P57Q | Missense Mutation (SNP) | VAF 150/492 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- EXPH5 | c.3838G>C p.E1280Q | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); called by muse, mutect2
- EXPH5 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- FAM187B | c.197T>A p.L66H | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- FAT3 | c.4933G>A p.D1645N | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBXW8 | c.388G>C p.V130L (on ENST00000309909; = p.V168L on NM_012174.1) | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FGGY | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FIG4 | c.1450A>C p.T484P | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FKBP9 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FLI1 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 54/421 reads (13%) | called by muse, mutect2, varscan2
- FRMPD4 | c.2838dup p.A947Cfs*28 | Frame Shift Ins (INS) | VAF 61/146 reads (42%) | called by mutect2, pindel, varscan2
- FSIP1 | c.908G>T p.W303L | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- GABRG1 | c.830C>A p.T277N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GANC | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 13/64 reads (20%) | PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- GASK1A | c.800A>T p.Q267L | Missense Mutation (SNP) | VAF 39/277 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- GATAD2B | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GK3P | c.52C>A p.Q18K | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- GLB1L2 | c.1904T>A p.I635N | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- GLRA2 | c.981T>G p.F327L | Missense Mutation (SNP) | VAF 103/177 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- GOLGB1 | c.7801T>G p.S2601A | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPRIN3 | c.326C>G p.A109G | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- GRM5 | c.3206C>A p.T1069K (on ENST00000305447 / NM_001143831.2; = p.T1037K on NM_000842.4) | Missense Mutation (SNP) | VAF 113/436 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- GRM8 | c.1529C>A p.T510N | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2
- GRM8 | c.957T>A p.Y319* | Nonsense Mutation (SNP) | VAF 56/160 reads (35%) | called by muse, mutect2, varscan2
- HAND2 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HEXIM1 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HLA-DQA2 | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 108/539 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- HSPA1B | c.1740G>T p.W580C | Missense Mutation (SNP) | VAF 228/802 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- IFT46 | c.425C>T p.S142L (on ENST00000264021 / NM_001168618.2; = p.S193L on NM_020153.3) | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- IL1RAPL1 | c.492C>A p.C164* | Nonsense Mutation (SNP) | VAF 86/160 reads (54%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.1330T>A p.Y444N | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- IL6 | c.323A>T p.E108V | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); called by muse, mutect2
- IRAG1 | c.116_118dup p.E39dup | In Frame Ins (INS) | VAF 38/293 reads (13%) | called by mutect2, pindel, varscan2
- ITGB2 | c.1272T>A p.C424* (on ENST00000302347; = p.C400* on NM_000211.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 46/333 reads (14%) | called by muse, mutect2, varscan2
- KCNJ3 | c.1127T>C p.I376T | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCTD14 | c.283A>T p.T95S | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KIAA1671 | c.4862G>T p.C1621F | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.558); called by muse, mutect2
- KIF19 | c.688C>A p.Q230K | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- KIF26A | c.2377G>T p.V793L | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KLF5 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2
- KRT1 | c.1784G>A p.G595D | Missense Mutation (SNP) | VAF 75/474 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- KRTAP6-3 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 38/480 reads (8%) | PolyPhen probably damaging (0.994); called by muse, mutect2
- LAMA2 | c.2040T>A p.N680K | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.247); called by muse, mutect2
- LIG4 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LILRA1 | c.452T>A p.F151Y | Missense Mutation (SNP) | VAF 87/289 reads (30%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- LIN54 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 33/320 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- LMTK2 | c.4040A>C p.E1347A | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LMX1A | c.566G>C p.G189A | Missense Mutation (SNP) | VAF 37/309 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- LPGAT1 | c.445A>T p.I149L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- LRBA | c.6227G>T p.G2076V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRBA | c.216+2T>A p.X72_splice | Splice Site (SNP) | VAF 19/132 reads (14%) | called by muse, mutect2
- LRCH1 | c.1383G>T p.L461F | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRP1B | c.1173G>T p.L391F | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- LRP8 | c.1137G>C p.E379D | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC53 | c.1495C>A p.R499S | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRTM4 | c.1007C>A p.T336N | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LYST | c.3961G>T p.G1321* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- MAGEB1 | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 88/114 reads (77%) | SIFT tolerated (0.12); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- MAGEB4 | c.571A>T p.S191C | Missense Mutation (SNP) | VAF 120/188 reads (64%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MAP3K19 | c.3956T>C p.L1319P | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCAM | c.1332G>C p.E444D | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MIS18BP1 | c.1218A>G p.I406M | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.089); called by muse, mutect2
- MPZL2 | c.226-2dup p.X76_splice | Splice Site (INS) | VAF 31/206 reads (15%) | called by mutect2, pindel
- MRPS35 | c.671A>T p.Y224F | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MSRB3 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTMR4 | c.3233G>A p.G1078D | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MTRR | c.1990G>A p.A664T (on ENST00000264668; = p.A637T on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/296 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MUC12 | c.2629G>T p.A877S (on ENST00000379442; = p.A734S on NM_001164462.1) | Missense Mutation (SNP) | VAF 50/1629 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.374); called by muse, mutect2
- MXRA8 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 85/263 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYH4 | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, varscan2
- MYOZ2 | c.124A>T p.I42F | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYT1L | c.2437G>C p.D813H | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- NBPF6 | c.1747+1G>T p.X583_splice | Splice Site (SNP) | VAF 27/181 reads (15%) | called by muse, mutect2, varscan2
- NEB | c.26A>C p.E9A | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- NOTCH1 | c.3476_3483dup p.D1162Pfs*20 | Frame Shift Ins (INS) | VAF 149/494 reads (30%) | called by mutect2, varscan2
- NOX4 | c.166C>G p.L56V | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NPY5R | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NXPE2 | c.1593G>T p.M531I | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ODAM | c.322G>T p.V108F | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OGDH | c.586G>T p.G196* | Nonsense Mutation (SNP) | VAF 14/100 reads (14%) | called by muse, mutect2, varscan2
- OR1E1 | c.91T>C p.F31L | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- OR2M4 | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- OR51A4 | c.255C>A p.S85R | Missense Mutation (SNP) | VAF 40/375 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5AS1 | c.433A>T p.I145F | Missense Mutation (SNP) | VAF 116/325 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR5F1 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR5L1 | c.674T>C p.I225T | Missense Mutation (SNP) | VAF 79/357 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- PACS1 | c.2093C>A p.P698Q | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PANK1 | c.1436A>T p.Y479F | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PAPOLA | c.2114A>T p.Q705L | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2
- PAPPA2 | c.796T>A p.S266T | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PARD6A | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 65/293 reads (22%) | called by muse, mutect2, varscan2
- PASK | c.1558G>A p.V520M | Missense Mutation (SNP) | VAF 15/413 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.088); called by muse, mutect2
- PCDH9 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 46/128 reads (36%) | called by muse, mutect2, varscan2
- PDE4DIP | c.3748_3757del p.K1250Lfs*9 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- PDILT | c.338T>G p.F113C | Missense Mutation (SNP) | VAF 96/406 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PELI2 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PEX6 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 109/413 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- PEX7 | c.385_387dup p.V129dup | In Frame Ins (INS) | VAF 108/309 reads (35%) | called by mutect2, pindel, varscan2
- PIWIL1 | c.1648A>T p.T550S | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PIWIL1 | c.1649C>T p.T550I | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PLAA | c.644G>T p.R215I | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- PLCD4 | c.859C>G p.P287A | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PLCXD3 | c.929T>C p.L310P | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PLCZ1 | c.577G>C p.V193L | Missense Mutation (SNP) | VAF 57/260 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PLD5 | c.858A>T p.R286S (on ENST00000442594; = p.R224S on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.132); called by muse, mutect2
- PLD5 | c.857G>T p.R286I (on ENST00000442594; = p.R224I on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2
- PLEKHM1 | c.2360T>A p.V787E | Missense Mutation (SNP) | VAF 68/536 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLXNA1 | c.5387C>T p.P1796L | Missense Mutation (SNP) | VAF 68/217 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPARG | c.238G>C p.D80H (on ENST00000287820 / NM_015869.5; = p.D50H on NM_005037.7) | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PPP4R1 | c.1117A>T p.S373C (on ENST00000400556 / NM_001042388.3; = p.S356C on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRAMEF11 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 50/616 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- PRRT3 | c.2171_2202del p.S724* | Frame Shift Del (DEL) | VAF 86/460 reads (19%) | called by mutect2, pindel
- PRSS36 | c.495C>A p.H165Q | Missense Mutation (SNP) | VAF 112/519 reads (22%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PTCH2 | c.3022G>C p.G1008R | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRM | c.2404T>A p.C802S | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.049); called by muse, mutect2
- RABEP2 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 65/569 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- RAD17 | c.575A>T p.Q192L (on ENST00000380774 / NM_133339.2; = p.Q181L on NM_002873.1) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- RAPGEF3 | c.2144A>C p.Q715P (on ENST00000389212; = p.Q673P on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/435 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RC3H1 | c.1463G>A p.R488K | Missense Mutation (SNP) | VAF 47/352 reads (13%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- RESF1 | c.1690G>T p.V564F | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- RNF144A | c.96G>A p.M32I | Missense Mutation (SNP) | VAF 71/259 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- SAG | c.667C>G p.P223A | Missense Mutation (SNP) | VAF 37/323 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SBF1 | c.436A>C p.R146= | Splice Region (SNP) | VAF 43/158 reads (27%) | called by muse, mutect2, varscan2
- SEMA5A | c.539A>G p.Y180C | Missense Mutation (SNP) | VAF 126/514 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SEPTIN6 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SETBP1 | c.4513A>G p.I1505V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC12A5 | c.872T>C p.L291P (on ENST00000454036 / NM_001134771.2; = p.L268P on NM_020708.5) | Missense Mutation (SNP) | VAF 86/322 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SLC19A2 | c.462C>A p.Y154* | Nonsense Mutation (SNP) | VAF 44/526 reads (8%) | called by muse, mutect2
- SLC25A52 | c.143G>T p.C48F (on ENST00000672005; = p.C38F on NM_001034172.4) | Missense Mutation (SNP) | VAF 74/225 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC26A1 | c.1160C>A p.P387H | Missense Mutation (SNP) | VAF 126/383 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC2A13 | c.1285C>A p.P429T | Missense Mutation (SNP) | VAF 10/267 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2
- SLC38A1 | c.1215C>A p.N405K | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC44A1 | c.1362A>C p.K454N | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- SLC8A1 | c.1649G>C p.S550T | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- SLITRK2 | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- SMARCA4 | c.256del p.D86Tfs*8 | Frame Shift Del (DEL) | VAF 126/458 reads (28%) | called by mutect2, pindel, varscan2
- SMG1 | c.9607C>G p.Q3203E | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2
- SMG8 | c.2398A>T p.I800F | Missense Mutation (SNP) | VAF 45/339 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- SORBS1 | c.1361-1G>C p.X454_splice (on ENST00000361941 / NM_001034954.2; = p.X244_splice on NM_006434.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- SORBS2 | c.703T>G p.S235A (on ENST00000284776 / NM_021069.5; = p.S328A on NM_003603.6) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.097); called by muse, varscan2
- SPAG6 | c.121+3G>C | Splice Region (SNP) | VAF 41/389 reads (11%) | called by muse, mutect2, varscan2
- SPEF2 | c.119A>T p.K40M | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPEG | c.4414A>G p.T1472A | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- SPTBN4 | c.5167C>G p.L1723V | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ST13 | c.812G>C p.R271T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); called by muse, mutect2
- STAB2 | c.4925A>T p.E1642V | Missense Mutation (SNP) | VAF 80/363 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- STK11IP | c.2620C>T p.Q874* | Nonsense Mutation (SNP) | VAF 43/247 reads (17%) | called by muse, mutect2, varscan2
- SUPT6H | c.4371C>G p.F1457L | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- SUSD5 | c.1212C>A p.N404K | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SYK | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 44/98 reads (45%) | called by muse, varscan2
- TAF2 | c.788A>G p.H263R | Missense Mutation (SNP) | VAF 88/349 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- TAFA5 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TAGLN3 | c.401G>T p.S134I | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- TBATA | c.1001T>A p.M334K | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- TENM3 | c.1292A>T p.Y431F | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- TIMM44 | c.476_477insT p.A160Gfs*32 | Frame Shift Ins (INS) | VAF 75/456 reads (16%) | called by mutect2, pindel, varscan2
- TMED5 | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMED5 | c.595T>A p.S199T | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM127 | c.436T>A p.F146I | Missense Mutation (SNP) | VAF 40/313 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TMEM132C | c.1750C>G p.Q584E | Missense Mutation (SNP) | VAF 74/315 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- TMEM132C | c.2806del p.L936Wfs*7 | Frame Shift Del (DEL) | VAF 32/188 reads (17%) | called by mutect2, pindel, varscan2
- TMEM132D | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 47/409 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- TMEM68 | c.642G>T p.W214C | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMTC2 | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TOR1B | c.173G>C p.R58P | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TPK1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 137/279 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- TPR | c.5798C>G p.S1933C | Missense Mutation (SNP) | VAF 23/262 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.237); called by muse, mutect2
- TSPY1 | c.379A>T p.R127W | Missense Mutation (SNP) | VAF 52/744 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); called by muse, mutect2
- TTN | c.87116C>T p.T29039I (on ENST00000591111; = p.T21615I on NM_003319.4) | Missense Mutation (SNP) | VAF 19/151 reads (13%) | PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- TTN | c.58648C>A p.P19550T (on ENST00000591111; = p.P12126T on NM_003319.4) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.43442G>T p.G14481V (on ENST00000591111; = p.G7057V on NM_003319.4) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.43031C>G p.P14344R (on ENST00000591111; = p.P6920R on NM_003319.4) | Missense Mutation (SNP) | VAF 71/487 reads (15%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC13C | c.3505A>C p.T1169P | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- UNC13C | c.6199+2T>C p.X2067_splice | Splice Site (SNP) | VAF 28/150 reads (19%) | called by muse, mutect2, varscan2
- UPF2 | c.1026G>T p.E342D | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- USP29 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); called by muse, varscan2
- UXS1 | c.584C>A p.A195D | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VDR | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- WDR7 | c.2541G>C p.M847I | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- WDR70 | c.743C>G p.S248C | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- WDR77 | c.479T>G p.L160R | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- WTAP | c.573G>C p.K191N | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF212 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 114/240 reads (48%) | called by muse, mutect2, varscan2
- ZNF28 | c.2111C>G p.S704* | Nonsense Mutation (SNP) | VAF 28/160 reads (18%) | called by muse, varscan2
- ZNF443 | c.1262A>G p.H421R | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- ZNF471 | c.912C>G p.H304Q | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- ZNF582 | c.127G>T p.V43F | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ZNF716 | c.1294G>T p.G432* | Nonsense Mutation (SNP) | VAF 22/112 reads (20%) | called by muse, varscan2
- ZNF727 | c.245C>A p.T82N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.206); called by muse, mutect2
- ZNF771 | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- ZNF799 | c.682A>T p.K228* | Nonsense Mutation (SNP) | VAF 64/163 reads (39%) | called by muse, mutect2, varscan2
- ZNF99 | c.2289T>A p.C763* | Nonsense Mutation (SNP) | VAF 39/120 reads (33%) | called by muse, mutect2, varscan2
- ZNRD2 | c.25G>C p.D9H | Missense Mutation (SNP) | VAF 70/233 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- ADGRA1 | c.1074A>T p.P358= | Silent (SNP) | VAF 44/237 reads (19%) | called by muse, mutect2, varscan2
- AK9 | c.5289C>T p.N1763= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- ANO3 | c.165C>G p.S55= | Silent (SNP) | VAF 35/454 reads (8%) | called by muse, mutect2
- ARHGAP29 | c.2526G>A p.L842= | Silent (SNP) | VAF 15/90 reads (17%) | called by muse, mutect2, varscan2
- ARHGEF40 | c.4077C>T p.I1359= | Silent (SNP) | VAF 155/493 reads (31%) | called by muse, mutect2, varscan2
- ASCC3 | c.1899G>T p.R633= | Silent (SNP) | VAF 7/171 reads (4%) | called by muse, mutect2
- ASCC3 | c.654A>G p.T218= | Silent (SNP) | VAF 6/151 reads (4%) | called by muse, mutect2
- ATXN3 | c.1008A>T p.P336= | Silent (SNP) | VAF 81/399 reads (20%) | called by muse, mutect2, varscan2
- BPTF | c.3225A>G p.S1075= | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, varscan2
- BRSK1 | c.168G>C p.T56= | Silent (SNP) | VAF 40/249 reads (16%) | catalogued as COSV58664398; called by muse, mutect2, varscan2
- C10orf120 | c.918C>T p.D306= | Silent (SNP) | VAF 22/154 reads (14%) | called by muse, mutect2, varscan2
- C10orf71 | c.3021C>A p.P1007= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs545241202; called by muse, mutect2, varscan2
- C7 | c.1401T>C p.T467= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as COSV57475284; called by muse, mutect2, varscan2
- CACNA1E | c.3342G>A p.K1114= | Silent (SNP) | VAF 19/138 reads (14%) | called by muse, mutect2, varscan2
- CALCR | c.294T>C p.Y98= | Silent (SNP) | VAF 21/149 reads (14%) | called by muse, mutect2, varscan2
- CDC25C | c.817C>T p.L273= | Silent (SNP) | VAF 16/188 reads (9%) | called by muse, mutect2
- CDH22 | c.1092C>T p.F364= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100952833; called by muse, mutect2, varscan2
- CDK14 | c.1374T>C p.N458= (on ENST00000380050 / NM_001287135.2; = p.N440= on NM_012395.3) | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as rs760623974; called by muse, mutect2, varscan2
- CELF6 | c.1389C>T p.G463= | Silent (SNP) | VAF 44/233 reads (19%) | called by muse, mutect2, varscan2
- CNOT4 | c.849C>T p.L283= (on ENST00000315544 / NM_001190848.1; = p.L280= on NM_013316.4) | Silent (SNP) | VAF 46/129 reads (36%) | called by muse, varscan2
- CPA1 | c.660C>T p.V220= | Silent (SNP) | VAF 23/364 reads (6%) | catalogued as rs550805841; called by muse, mutect2
- DAB2IP | c.1098C>T p.I366= (on ENST00000408936; = p.I338= on NM_032552.3) | Silent (SNP) | VAF 37/88 reads (42%) | called by muse, mutect2, varscan2
- DCC | c.3753C>A p.I1251= | Silent (SNP) | VAF 86/280 reads (31%) | called by muse, mutect2, varscan2
- DCLK3 | c.1125C>T p.H375= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as rs1429445119, COSV69363777; called by muse, mutect2, varscan2
- DNAH3 | c.11979C>T p.H3993= | Silent (SNP) | VAF 76/307 reads (25%) | catalogued as rs774335671, COSV99767388; called by muse, mutect2, varscan2
- DNAH5 | c.2769C>T p.D923= | Silent (SNP) | VAF 33/320 reads (10%) | called by muse, mutect2, varscan2
- DNPEP | c.9A>C p.G3= | Silent (SNP) | VAF 38/169 reads (22%) | called by muse, mutect2, varscan2
- DOCK10 | c.403C>A p.R135= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV51421316; called by muse, mutect2, varscan2
- DOK4 | c.528C>T p.L176= | Silent (SNP) | VAF 147/504 reads (29%) | catalogued as rs944234470, COSV54671689; called by muse, mutect2, varscan2
- DSCAM | c.5820C>A p.P1940= | Silent (SNP) | VAF 19/227 reads (8%) | called by muse, mutect2
- EPM2AIP1 | c.360T>C p.F120= | Silent (SNP) | VAF 35/178 reads (20%) | called by muse, mutect2, varscan2
- ESRRB | c.1251C>T p.G417= | Silent (SNP) | VAF 218/514 reads (42%) | called by muse, mutect2, varscan2
- FAM71E2 | c.324C>T p.L108= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs961471384; called by muse, mutect2, varscan2
- FMN2 | c.1260G>A p.K420= | Silent (SNP) | VAF 29/123 reads (24%) | called by muse, mutect2, varscan2
- FMNL2 | c.1308C>G p.V436= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as COSV56492901; called by muse, mutect2, varscan2
- GALNT17 | c.1452G>T p.L484= | Silent (SNP) | VAF 48/214 reads (22%) | called by muse, mutect2, varscan2
- GJD2 | c.828A>T p.G276= | Silent (SNP) | VAF 54/338 reads (16%) | called by muse, mutect2, varscan2
- GSC2 | c.27G>C p.A9= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1342000938; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1839A>G p.L613= | Silent (SNP) | VAF 52/276 reads (19%) | catalogued as rs1297816138; called by muse, varscan2
- H2BC4 | c.339G>C p.S113= | Silent (SNP) | VAF 176/486 reads (36%) | called by muse, mutect2, varscan2
- HECTD4 | c.12123C>G p.L4041= | Silent (SNP) | VAF 43/301 reads (14%) | called by muse, mutect2, varscan2
- HEXIM1 | c.717C>T p.D239= | Silent (SNP) | VAF 69/448 reads (15%) | called by muse, mutect2, varscan2
- HLA-DQA2 | c.588G>T p.L196= | Silent (SNP) | VAF 108/551 reads (20%) | called by muse, varscan2
- HTR1A | c.666G>T p.A222= | Silent (SNP) | VAF 104/464 reads (22%) | catalogued as COSV60500938, COSV60502320; called by muse, mutect2, varscan2
- HUS1B | c.639G>C p.S213= | Silent (SNP) | VAF 93/452 reads (21%) | called by muse, mutect2, varscan2
- HYDIN | c.11697G>A p.V3899= | Silent (SNP) | VAF 35/478 reads (7%) | called by muse, mutect2
- ICE1 | c.6675C>G p.P2225= | Silent (SNP) | VAF 36/390 reads (9%) | called by muse, mutect2
- IFNA6 | c.144T>C p.S48= | Silent (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- IGF2R | c.3189G>T p.G1063= | Silent (SNP) | VAF 79/231 reads (34%) | called by muse, mutect2, varscan2
- IGFBP3 | c.294C>T p.P98= | Silent (SNP) | VAF 62/281 reads (22%) | called by muse, mutect2, varscan2
- KCNQ2 | c.1965C>T p.T655= (on ENST00000359125 / NM_172107.4; = p.T627= on NM_004518.6) | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as rs755777278, COSV60548502; called by muse, mutect2, varscan2
- KCNS1 | c.528C>T p.S176= | Silent (SNP) | VAF 83/262 reads (32%) | catalogued as rs1194823861, COSV100067247; called by muse, mutect2, varscan2
- KIAA1109 | c.7410A>C p.S2470= | Silent (SNP) | VAF 21/200 reads (11%) | catalogued as rs760817271, COSV99151538; called by muse, mutect2, varscan2
- KIAA2012 | c.273C>A p.G91= | Silent (SNP) | VAF 73/280 reads (26%) | called by muse, mutect2, varscan2
- KIF21A | c.2946G>T p.V982= (on ENST00000361418 / NM_001378440.1; = p.V969= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2, varscan2
- KIF5C | c.243G>C p.T81= | Silent (SNP) | VAF 24/178 reads (13%) | called by muse, mutect2, varscan2
- KRTAP10-10 | c.258C>T p.T86= | Silent (SNP) | VAF 132/439 reads (30%) | catalogued as rs1555937200; called by muse, mutect2, varscan2
- LAMA5 | c.10356G>T p.P3452= | Silent (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- LRP1B | c.5526T>C p.N1842= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as rs138541397; called by muse, mutect2, varscan2
- LRRCC1 | c.816T>G p.S272= | Silent (SNP) | VAF 38/208 reads (18%) | called by muse, mutect2, varscan2
- MAGI3 | c.504C>T p.F168= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as rs1352579199; called by muse, mutect2, varscan2
- MON1B | c.558G>T p.L186= | Silent (SNP) | VAF 91/329 reads (28%) | called by muse, mutect2, varscan2
- NEK1 | c.2310G>C p.L770= | Silent (SNP) | VAF 54/155 reads (35%) | called by muse, mutect2, varscan2
- NLRP8 | c.375G>T p.L125= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs1207571886; called by muse, mutect2, varscan2
- NR5A2 | c.663A>G p.K221= (on ENST00000367362 / NM_205860.3; = p.K175= on NM_003822.5) | Silent (SNP) | VAF 51/188 reads (27%) | called by muse, mutect2, varscan2
- NRN1 | c.261G>A p.A87= | Silent (SNP) | VAF 22/486 reads (5%) | catalogued as COSV55205450, COSV99784311; called by muse, mutect2
- OGDHL | c.2001G>A p.R667= | Silent (SNP) | VAF 15/111 reads (14%) | called by muse, mutect2
- OR4A47 | c.639C>A p.L213= | Silent (SNP) | VAF 63/228 reads (28%) | called by muse, mutect2, varscan2
- OR5H2 | c.186C>A p.I62= | Silent (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- OR8H2 | c.72C>A p.I24= | Silent (SNP) | VAF 73/203 reads (36%) | catalogued as COSV57943031; called by muse, mutect2, varscan2
- PCSK1N | c.630G>A p.E210= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as rs781807803, COSV54433193; called by muse, varscan2
- PDE1C | c.741A>T p.T247= | Silent (SNP) | VAF 23/126 reads (18%) | called by muse, mutect2
- PFKL | c.1074G>T p.V358= | Silent (SNP) | VAF 14/202 reads (7%) | catalogued as COSV62463294; called by muse, mutect2
- PHKA2 | c.45G>A p.A15= | Silent (SNP) | VAF 16/467 reads (3%) | called by muse, mutect2
- PKMYT1 | c.1011C>T p.V337= | Silent (SNP) | VAF 37/301 reads (12%) | called by muse, mutect2, varscan2
- PLEKHH1 | c.1854G>T p.R618= | Silent (SNP) | VAF 33/252 reads (13%) | called by muse, mutect2, varscan2
- PLXND1 | c.3564G>A p.K1188= | Silent (SNP) | VAF 30/220 reads (14%) | catalogued as rs988170028, COSV60709469; called by muse, mutect2, varscan2
- PPP1R12B | c.1410C>T p.R470= | Silent (SNP) | VAF 98/471 reads (21%) | called by muse, mutect2, varscan2
- PRKAA2 | c.1218C>T p.I406= | Silent (SNP) | VAF 15/127 reads (12%) | catalogued as COSV100983016; called by muse, mutect2, varscan2
- PTCD2 | c.384G>A p.G128= | Silent (SNP) | VAF 12/173 reads (7%) | called by muse, mutect2
- PTPN23 | c.1911C>T p.Y637= | Silent (SNP) | VAF 38/218 reads (17%) | catalogued as rs778078873, COSV99650755; called by muse, mutect2, varscan2
- RIMS2 | c.1392T>A p.S464= (on ENST00000666250 / NM_001348490.2; = p.S272= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 85/369 reads (23%) | called by muse, mutect2, varscan2
- ROBO1 | c.1371T>A p.I457= | Silent (SNP) | VAF 23/167 reads (14%) | called by muse, mutect2, varscan2
- RRAGA | c.861G>T p.L287= | Silent (SNP) | VAF 101/236 reads (43%) | called by muse, mutect2, varscan2
- RTN1 | c.1884C>T p.A628= | Silent (SNP) | VAF 195/570 reads (34%) | called by muse, mutect2, varscan2
- RYR2 | c.5419C>A p.R1807= | Silent (SNP) | VAF 63/275 reads (23%) | catalogued as COSV63690057; called by muse, mutect2, varscan2
- SFTA2 | c.117C>G p.S39= | Silent (SNP) | VAF 42/144 reads (29%) | called by muse, mutect2, varscan2
- SI | c.1812C>T p.D604= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs1336764474; called by muse, mutect2, varscan2
- SIPA1L3 | c.1119G>A p.S373= | Silent (SNP) | VAF 52/228 reads (23%) | catalogued as rs574587415; called by muse, mutect2, varscan2
- SLC6A12 | c.1719C>T p.I573= | Silent (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- SLITRK4 | c.2391C>A p.G797= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs781788013; called by muse, mutect2, varscan2
- SNX31 | c.90G>C p.G30= | Silent (SNP) | VAF 24/245 reads (10%) | catalogued as rs757052809; called by muse, mutect2, varscan2
- SPTA1 | c.2019G>A p.L673= | Silent (SNP) | VAF 36/370 reads (10%) | called by muse, mutect2
- SPTB | c.2953C>A p.R985= | Silent (SNP) | VAF 173/519 reads (33%) | called by muse, mutect2, varscan2
- STK11IP | c.2175C>T p.P725= | Silent (SNP) | VAF 50/352 reads (14%) | catalogued as rs1296379973; called by muse, mutect2, varscan2
- STX11 | c.756G>C p.T252= | Silent (SNP) | VAF 97/267 reads (36%) | called by muse, mutect2, varscan2
- STYXL2 | c.339C>G p.P113= | Silent (SNP) | VAF 31/428 reads (7%) | called by muse, mutect2
- SYNE1 | c.9657C>A p.V3219= (on ENST00000367255 / NM_182961.4; = p.V3226= on NM_033071.3) | Silent (SNP) | VAF 93/248 reads (38%) | called by muse, mutect2, varscan2
- SYNE2 | c.897G>T p.V299= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs1171469078; called by muse, mutect2, varscan2
- TBX19 | c.795C>A p.A265= | Silent (SNP) | VAF 210/552 reads (38%) | called by muse, mutect2, varscan2
- THAP5 | c.828A>G p.V276= (on ENST00000415914 / NM_001130475.3; = p.V234= on NM_182529.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs776220737; called by muse, mutect2, varscan2
- THSD7B | c.4170T>C p.D1390= (on ENST00000272643; = p.D1388= on NM_001316349.2) | Silent (SNP) | VAF 15/155 reads (10%) | catalogued as COSV55650362; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.492G>A p.K164= | Silent (SNP) | VAF 25/129 reads (19%) | called by muse, mutect2, varscan2
- TRAV14DV4 | c.12T>C p.S4= | Silent (SNP) | VAF 41/169 reads (24%) | called by muse, mutect2
- TTN | c.86859T>A p.R28953= (on ENST00000591111; = p.R21529= on NM_003319.4) | Silent (SNP) | VAF 20/130 reads (15%) | called by muse, mutect2
- UMODL1 | c.1119G>T p.L373= | Silent (SNP) | VAF 48/329 reads (15%) | catalogued as COSV61160877; called by muse, mutect2, varscan2
- UNC5D | c.648G>T p.L216= | Silent (SNP) | VAF 55/92 reads (60%) | called by muse, mutect2, varscan2
- VAV2 | c.607C>T p.L203= (on ENST00000371850 / NM_001134398.2; = p.L198= on NM_003371.4) | Silent (SNP) | VAF 43/136 reads (32%) | called by muse, mutect2, varscan2
- ZEB2 | c.579G>T p.G193= | Silent (SNP) | VAF 27/195 reads (14%) | catalogued as rs1291713413; called by muse, mutect2, varscan2
- ZNF615 | c.1251A>T p.V417= | Silent (SNP) | VAF 22/147 reads (15%) | called by muse, mutect2, varscan2
- ZNF679 | c.804C>T p.Y268= | Silent (SNP) | VAF 21/121 reads (17%) | called by muse, mutect2, varscan2
- ZNF799 | c.249A>G p.T83= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs1196466901; called by muse, varscan2
- AC005400.1 | n.179-2725A>C | Intron (SNP) | VAF 6/26 reads (23%) | called by muse, varscan2
- AC068580.4 | c.-13G>T | 5'UTR (SNP) | VAF 53/298 reads (18%) | called by muse, mutect2, varscan2
- ACBD5 | chr10:27196312 C>T | 3'Flank (SNP) | VAF 66/591 reads (11%) | called by muse, mutect2, varscan2
- AL033381.1 | n.392A>T | RNA (SNP) | VAF 48/180 reads (27%) | called by muse, mutect2, varscan2
- ANKRD33B | c.496+6321C>T | Intron (SNP) | VAF 64/382 reads (17%) | called by muse, mutect2, varscan2
- AOC4P | n.1597+85del | Intron (DEL) | VAF 11/50 reads (22%) | called by mutect2, pindel, varscan2
- ARHGEF7 | c.166-51G>C | Intron (SNP) | VAF 60/241 reads (25%) | called by muse, mutect2, varscan2
- ATE1 | c.942+978C>G | Intron (SNP) | VAF 15/144 reads (10%) | called by muse, mutect2, varscan2
- CCDC136 | c.-27C>T | 5'UTR (SNP) | VAF 83/212 reads (39%) | catalogued as COSV52804790; called by muse, mutect2, varscan2
- CHD8 | c.6772-279G>A | Intron (SNP) | VAF 27/122 reads (22%) | catalogued as rs771318761; called by muse, mutect2, varscan2
- CHL1 | c.-24G>T | 5'UTR (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- CLPS | c.84+385C>T | Intron (SNP) | VAF 43/184 reads (23%) | called by muse, mutect2, varscan2
- CSGALNACT1 | c.851+716A>G | Intron (SNP) | VAF 152/284 reads (54%) | called by muse, mutect2, varscan2
- DCHS2 | n.4311C>A | RNA (SNP) | VAF 28/85 reads (33%) | called by muse, mutect2, varscan2
- DCHS2 | n.3355G>C | RNA (SNP) | VAF 41/224 reads (18%) | catalogued as COSV59737742; called by muse, mutect2, varscan2
- DDX39A | c.-5+256C>T | Intron (SNP) | VAF 34/170 reads (20%) | called by muse, mutect2, varscan2
- FBXL7 | c.-24G>A | 5'UTR (SNP) | VAF 143/633 reads (23%) | called by muse, mutect2, varscan2
- FER1L4 | n.4576C>A | RNA (SNP) | VAF 47/371 reads (13%) | called by muse, mutect2, varscan2
- FGFR2 | c.939+1227A>G | Intron (SNP) | VAF 74/410 reads (18%) | catalogued as rs1047087; called by muse, mutect2, varscan2
- FN1 | c.6442-19G>A | Intron (SNP) | VAF 31/254 reads (12%) | called by muse, mutect2, varscan2
- FOLH1B | n.1493T>C | RNA (SNP) | VAF 21/149 reads (14%) | catalogued as rs1380890347; called by muse, mutect2, varscan2
- FRMPD2B | n.456C>A | RNA (SNP) | VAF 124/1310 reads (9%) | called by muse, mutect2
- GALC | c.*776G>T | 3'UTR (SNP) | VAF 23/133 reads (17%) | called by muse, mutect2, varscan2
- GBA3 | c.59-8351del | Intron (DEL) | VAF 45/170 reads (26%) | called by mutect2, pindel, varscan2
- GLIS2 | c.-33C>G | 5'UTR (SNP) | VAF 137/487 reads (28%) | called by muse, mutect2, varscan2
- GRM3 | c.-195G>T | 5'UTR (SNP) | VAF 58/268 reads (22%) | catalogued as rs1254274278; called by muse, mutect2, varscan2
- H2AC4 | c.*6T>G | 3'UTR (SNP) | VAF 62/247 reads (25%) | called by muse, mutect2, varscan2
- IMPDH2 | chr3:49029506 C>T | 5'Flank (SNP) | VAF 24/112 reads (21%) | called by muse, mutect2
- ITGB4 | c.4558+267G>A | Intron (SNP) | VAF 78/206 reads (38%) | called by muse, mutect2, varscan2
- KIAA0040 | c.-174G>C | 5'UTR (SNP) | VAF 22/180 reads (12%) | called by muse, varscan2
- LINC01550 | chr14:97978111 A>T | 5'Flank (SNP) | VAF 18/177 reads (10%) | called by muse, mutect2, varscan2
- LY6G6D | c.55+10C>T | Intron (SNP) | VAF 16/67 reads (24%) | catalogued as rs766131830; called by muse, mutect2, varscan2
- MAP1A | c.-144C>A | 5'UTR (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- MGAT5B | c.1025+7623A>G | Intron (SNP) | VAF 29/74 reads (39%) | catalogued as rs944955989; called by muse, mutect2, varscan2
- MGST3 | c.117+33G>T | Intron (SNP) | VAF 42/342 reads (12%) | called by muse, mutect2, varscan2
- MIR1283-2 | n.32T>G | RNA (SNP) | VAF 56/174 reads (32%) | called by muse, mutect2, varscan2
- MPZ | c.-4A>T | 5'UTR (SNP) | VAF 59/160 reads (37%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40546435 G>T | 3'Flank (SNP) | VAF 34/147 reads (23%) | called by muse, mutect2, varscan2
- NCDN | c.-23G>T | 5'UTR (SNP) | VAF 35/132 reads (27%) | called by muse, mutect2, varscan2
- NPFFR1 | c.-37C>G | 5'UTR (SNP) | VAF 37/211 reads (18%) | called by muse, mutect2, varscan2
- OR10V2P | n.216T>A | RNA (SNP) | VAF 33/101 reads (33%) | called by muse, mutect2, varscan2
- PPP1R16A | c.-19T>A | 5'UTR (SNP) | VAF 157/290 reads (54%) | called by muse, mutect2, varscan2
- PSG4 | c.*4C>G | 3'UTR (SNP) | VAF 61/238 reads (26%) | called by muse, mutect2, varscan2
- PTPRC | c.-17A>T | 5'UTR (SNP) | VAF 53/244 reads (22%) | catalogued as rs1371935250; called by muse, mutect2, varscan2
- PTPRC | c.*42G>T | 3'UTR (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
- RAB18 | c.*2662A>C | 3'UTR (SNP) | VAF 34/87 reads (39%) | called by muse, mutect2, varscan2
- RN7SL495P | chr15:22607833 G>T | 3'Flank (SNP) | VAF 15/107 reads (14%) | called by mutect2, varscan2
- SEC16B | c.1546-588C>T | Intron (SNP) | VAF 38/262 reads (15%) | called by muse, mutect2, varscan2
- SEPTIN2 | c.218-22A>G | Intron (SNP) | VAF 48/142 reads (34%) | catalogued as rs769432062; called by muse, mutect2, varscan2
- SLCO1B3 | c.1865+505C>A | Intron (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- SNORD116-17 | chr15:25088203 G>C | 3'Flank (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- STIMATE-MUSTN1 | c.*13A>T | 3'UTR (SNP) | VAF 82/424 reads (19%) | called by muse, mutect2, varscan2
- STUB1 | chr16:684475 G>A | 3'Flank (SNP) | VAF 63/182 reads (35%) | catalogued as rs1241056708; called by muse, mutect2, varscan2
- SUSD3 | c.89-6665T>A | Intron (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- SYNE1 | c.16390-37T>C | Intron (SNP) | VAF 54/143 reads (38%) | called by muse, varscan2
- TIMM50 | chr19:39480548 G>C | 5'Flank (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- TMBIM4 | c.97+637A>T | Intron (SNP) | VAF 11/53 reads (21%) | catalogued as rs1221091244; called by muse, mutect2, varscan2
- U8 | chr15:30585891 T>C | 3'Flank (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- UGP2 | c.147+378G>T | Intron (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- XAGE5 | c.*22C>G | 3'UTR (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
